Somatic mutation profile of tumor specimen TARGET-10-PARSNX-09A (aliquot TARGET-10-PARSNX-09A-01D) from TARGET case TARGET-10-PARSNX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,915 days).
Specimen TARGET-10-PARSNX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8743aed8-62dc-4995-aa41-d0ed060273a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARSNX-10A (Blood Derived Normal), aliquot TARGET-10-PARSNX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78eca26d-bf44-45e9-bf50-4cc9fcc1413e

The open-access MAF lists 33 somatic variants for this specimen: 20 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 9, Nonsense Mutation 5, 3'Flank 2, Splice Region 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD65 | c.47A>G p.Q16R | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.3); catalogued as COSV70987106; called by muse, mutect2, varscan2
- DNAJC13 | c.4993A>T p.K1665* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as rs1431326559, COSV53444955; called by muse, mutect2, varscan2
- GATA6 | c.406C>A p.L136M | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV52524944; called by muse, mutect2
- HERC2 | c.12268G>T p.G4090* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV55315394; called by muse, mutect2
- HSPA9 | c.630G>C p.Q210H | Missense Mutation (SNP) | VAF 100/249 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV51864020; called by muse, mutect2, varscan2
- NOTCH1 | c.7180C>T p.Q2394* | Nonsense Mutation (SNP) | VAF 21/296 reads (7%) | catalogued as COSV53037277; called by muse, mutect2
- PAPPA | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs570712795, COSV60280087; called by muse, mutect2, varscan2
- PRPS1L1 | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV72649856; called by muse, mutect2
- PXDNL | c.665C>A p.A222D | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV62487305; called by muse, mutect2
- QRICH1 | c.1531C>T p.R511* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as rs746059690, COSV62614946; called by muse, mutect2, varscan2
- SOX2 | c.492C>A p.N164K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100327382; called by muse, mutect2
- TMEM255B | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100943159, COSV64703697, COSV64705055; called by muse, mutect2, varscan2
- ADAMTS10 | c.2741G>A p.R914H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CEP104 | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.103); called by muse, mutect2
- FOXC2 | c.1256C>A p.A419E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2
- FZD5 | c.1381G>T p.A461S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); called by muse, mutect2
- SLC12A2 | c.3436-3C>A | Splice Region (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- UGGT1 | c.4604C>A p.A1535E | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- USP7 | c.903_904insTATTAACCTCCCTGA p.R301_V302insY* | Nonsense Mutation (INS) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- ZNF879 | c.832C>A p.H278N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BEST1 | c.729G>A p.A243= | Silent (SNP) | VAF 15/241 reads (6%) | catalogued as rs752998391; called by muse, mutect2
- ESPN | c.2190G>A p.P730= | Silent (SNP) | VAF 57/134 reads (43%) | catalogued as rs147668963; called by muse, mutect2, varscan2
- FLNA | c.5715G>T p.P1905= (on ENST00000369850 / NM_001110556.2; = p.P1897= on NM_001456.3) | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2
- KCNK17 | c.681C>T p.Y227= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs1041159756, COSV100950152; called by muse, mutect2
- KPNB1 | c.1179C>A p.I393= | Silent (SNP) | VAF 6/135 reads (4%) | called by muse, mutect2
- MAS1 | c.654G>A p.T218= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs758145350, COSV53120837; called by muse, mutect2, varscan2
- PKHD1L1 | c.1951C>T p.L651= | Silent (SNP) | VAF 8/66 reads (12%) | called by mutect2, varscan2
- PRAMEF15 | c.999C>A p.I333= | Silent (SNP) | VAF 128/392 reads (33%) | called by muse, mutect2, varscan2
- RBP4 | c.198C>T p.D66= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs142149253; called by muse, mutect2, varscan2
- ARF5 | chr7:127591989 C>A | 3'Flank (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- BAGE2 | n.226T>G | RNA (SNP) | VAF 28/210 reads (13%) | called by muse, varscan2
- CICP28 | chr7:56812186 T>C | 3'Flank (SNP) | VAF 10/36 reads (28%) | catalogued as rs12674218; called by muse, varscan2
- CSF2RA | c.*189C>G | 3'UTR (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2
